Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2Q1, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2Q1-01A (Primary Tumor).

[page 1 of 3]
	lw 8/31/11	

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

History of hashimoto's FNA PTC enlarged lymph nodes on ultrasound.

Specimens Submitted:

- 1: Total thyroid
- 2: Right tracheo-esophagea groove and pre-tracheal lymph node
- 3: Left tracheo-esophageal groove node
- 4: Right neck nodes levels three and four

DIAGNOSIS:

1. Total thyroid:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Right lobe and isthmus

Tumor Size:

Greatest diameter is 1.6 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Tumor is present less than 0.5 mm from surgical margin

Tumor Multicentricity:

Papillary microcarcinomas, five foci (left lobe: three foci, 0.1 cm to 0.3 cm in greatest dimension; right lobe: two foci, 0.5 cm and 0.1 cm in greatest dimension)

1CB-0-3
Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
lw
8/31/11

[page 2 of 3]
Adenoma(s) (away from the carcinoma):

Not Identified

Non-Neoplastic Thyroid:

Exhibits chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis

Parathyroid Glands:

Not Identified

2. Right tracheo-esophagea grove and pre-tracheal lymph node:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma

Number of lymph nodes examined: 12

Number of lymph nodes with metastatic disease: 6

Size of the largest lymph node involved by tumor: 1.3cm.

Size of the largest metastatic focus : 0.7 cm.

Extranodal extension is Identified

One unremarkable parathyroid gland identified

Comment: Extranodal extension is focal.

3. Left tracheo-esophageal grove node:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 5

4. Right neck nodes levels three and four:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma

Number of lymph nodes examined: 27

Number of lymph nodes with metastatic disease: 5

Size of the largest lymph node involved by tumor: 1.2cm.

Size of the largest metastatic focus : 1.0 cm.

Extranodal extension is not Identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

J.D./I

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh, labeled "Total thyroid" and consists of a 15.5 g, thyroid. The right lobe measures 4.0 x 3.1 x 1.6 cm, the left lobe measures 3.7 x 2.3 x 1.1 cm and the isthmus and pyramidal lobe measures 2.7 x 1.6 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.6 x 1.6 x 1.0 cm, firm, poorly defined, slightly bulging, tan-white nodule partially surrounded by a thin fibrotic rim, located within the right mid lobe, focally abutting the anterior and posterior capsule. The remaining parenchyma is meaty, tan-pink to patchy pale yellow. A portion of the nodule is submitted to TPS. The remaining tissue is entirely submitted for permanent.

Summary of sections:

N - nodule

[page 3 of 3]
RRL - remaining right lobe
LL - left lobe
IS - isthmus and pyramidal lobe

2. The specimen is received fresh, labeled "Right tracheoesophageal groove and pretracheal lymph node" and consists of a 4.2 x 1.5 x 0.5 cm aggregate of multiple fibrofatty tissue fragments, which are sectioned to reveal the 13, soft, ovoid, tan-pink lymph nodes, ranging from 0.3 to 1.4 cm in greatest dimension. The larger lymph nodes are bisected and all lymph nodes are entirely submitted.

Summary of sections:
LN -- lymph nodes
BLN -- bisected lymph nodes

3. The specimen is received fresh, labeled "Left tracheoesophageal groove node" and consists of five, soft, ovoid, tan-pink lymph nodes, ranging from 0.5 to 1.0 cm in greatest dimension. All five lymph nodes are bisected and entirely submitted.

Summary of sections:
BLN -- bisected lymph nodes

4. The specimen is received fresh, labeled "Right neck nodes, levels III & IV" and consists of an unoriented, 7.2 x 1.6 x 0.5 cm fibrofatty tissue fragment, which is sectioned to reveal 30, soft, ovoid, tan-pink lymph nodes, ranging from 0.1 to 1.5 cm in greatest dimension. The larger lymph nodes are bisected and all lymph nodes are entirely submitted.

Summary of sections:
LN -- lymph nodes
BLN -- bisected lymph nodes

Summary of Sections:

Part 1: Total thyroid

Block	Sect. Site	PCs
2	IS	7
6	LL	12
5	N	5
5	RRL	12

Part 2: Right tracheo-esophagea grove and pre-tracheal lymph node

Block	Sect. Site	PCs
5	BLN	10
2	LN	8

Part 3: Left tracheo-esophageal grove node

Block	Sect. Site	PCs
5	BLN	10

Part 4: Right neck nodes levels three and four

Block	Sect. Site	PCs
8	BLN	16
4	LN	22

Source: NCI Genomic Data Commons file 32333b3b-031f-43e9-b664-504a8a924868 (TCGA-DJ-A2Q1.5621D9A6-6B60-4EDC-AE6E-FAFD638DDE8E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).